Somatic mutation profile of tumor specimen TARGET-10-PAPDBX-09A (aliquot TARGET-10-PAPDBX-09A-01D) from TARGET case TARGET-10-PAPDBX, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.5 years (1,286 days).
Specimen TARGET-10-PAPDBX-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de3e1b14-e603-4187-9efd-c9968925b71b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPDBX-14A (Bone Marrow Normal), aliquot TARGET-10-PAPDBX-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ac3e7b5-cb8a-4573-a92b-a73f8a8e6e1f

The open-access MAF lists 22 somatic variants for this specimen: 19 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 16, Silent 3, Nonsense Mutation 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 22/100 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS17 | c.1691G>A p.R564H | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs756808653, COSV51493548; called by muse, mutect2, varscan2
- F9 | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 21/67 reads (31%) | catalogued as CM000149, CM121384; called by muse, mutect2, varscan2
- GRN | c.1226C>T p.T409M | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as rs373885474, CM134357, COSV50009692; called by muse, varscan2
- IZUMO2 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs367579131; called by muse, mutect2, varscan2
- PAX5 | c.547G>C p.G183R | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM139173, COSV63911050, COSV63911644; called by muse, mutect2, varscan2
- SLC30A3 | c.1042G>A p.V348I | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.05); catalogued as rs200925410; called by muse, mutect2, varscan2
- SRGAP3 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as rs200583663, COSV64532328; called by mutect2, varscan2
- USH2A | c.12905G>A p.R4302K | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.063); catalogued as COSV56431180; called by muse, mutect2, varscan2
- ABCC12 | c.2849C>T p.A950V | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2
- FBN2 | c.854G>A p.G285E | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- GPR156 | c.718G>T p.A240S | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.698); called by muse, mutect2
- KCNC2 | c.1316G>C p.G439A | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KDM4D | c.853C>T p.H285Y | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NEXMIF | c.1159G>T p.E387* | Nonsense Mutation (SNP) | VAF 32/91 reads (35%) | called by muse, mutect2, varscan2
- PAX5 | c.1099+1G>C p.X367_splice | Splice Site (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2, varscan2
- SEC14L1 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTN | c.31456G>A p.E10486K (on ENST00000591111; = p.E9559K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/104 reads (25%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF469 | c.11500C>A p.P3834T (on ENST00000437464; = p.P3862T on NM_001367624.2) | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.031); called by muse, mutect2
- CADPS2 | c.1401A>G p.K467= | Silent (SNP) | VAF 13/61 reads (21%) | called by muse, mutect2, varscan2
- CIC | c.3984C>A p.G1328= | Silent (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- PCDHB5 | c.1368C>T p.T456= | Silent (SNP) | VAF 26/202 reads (13%) | catalogued as rs1214135731; called by muse, mutect2, varscan2
